Surgical pathology report (de-identified scan), TCGA case TCGA-VQ-A8DV, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VQ-A8DV-01A (Primary Tumor).

Collect date:
(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Stomach (Antrum)

1 - "Stomach and epiploon":

Moderately differentiated adenocarcinoma, infiltrating until the muscle layer (intestinal type of Laurén).

Neoplasia measuring 4.3 cm in the greatest axis, located at gastric antrum.

Angiolymphatic and perineural infiltration: Not detected.

Necrosis: Not detected

Surgical margin uninvolved by neoplasia

All lymph nodes uninvolved by neoplasia among 16 dissected (0/16)

Epiploon uninvolved by neoplasia

Adjacent mucosa to tumor with moderate chronic gastritis and complete intestinal metaplasia. "H. pylori" positive

2 - "(11p) Splenic artery lymph node":

Uninvolved by neoplasia (0/3).

3 - "Esophageal margin":

Uninvolved by neoplasia

4 - "Enterectomy":

Uninvolved by neoplasia

Foci of bleeding of the wall with vascular congestion

5 - "Gallbladder":

Nonspecific chronic cholecystitis.

Adenocarcinoma, intestinal type
8/44/13

Site: Gastric antrum
C16.3

gn 11/23/13

Criteria	hu 10/21/13	Yes	No
Qual/S, synchronous Primary Noted			✓

Source: NCI Genomic Data Commons file b005f3fc-5864-422a-9bb1-6de25b3ca8ba (TCGA-VQ-A8DV.5141575A-2FB8-4BD0-A80E-EB88F8EAF63B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).